Surgical pathology report (de-identified scan), TCGA case TCGA-29-2431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2431-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-2431

Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling; ascites; per browser: CT scan on [REDACTED] reveals a complex pelvic mass involving both ovaries and the uterine fundus. There is also omental caking, peritoneal [REDACTED], and lymphadenopathy.

GROSS EXAMINATION:

A. "Right tube and ovary", received fresh and placed in formalin, is a 77 gram, 7 x 5.5 x 3.5 cm tan, nodular, friable mass with no recognizable ovarian tissue. There is a 4 x 0.4 cm section of fallopian tube which is also involved by tumor in the exterior surface where it is more proximal to the ovary. Representative sections are submitted in blocks A1-5.

B. "Left tube and ovary", received fresh and placed in formalin, is 36 gram, 4.5 x 3.5 x 3 cm tan, nodular, friable mass with no grossly evident ovarian tissue. There is a 2 x 0.4 cm section of fallopian tube which is not grossly involved by tumor. Representative sections are submitted in blocks B1-4.

C. "Uterus and cervix", received fresh and placed in formalin, is a 119 gram, 9 x 5.7 x 3.5 cm hysterectomy specimen with a 0.3 cm cervical os. The serosa, covering the fundus and the lower uterine segment, is studded by tan friable masses. The exterior, and more superior, part of the cervix is grossly involved by the tan friable masses. The endomyometrium is grossly unremarkable.

BLOCK SUMMARY:

- C1- posterior cervix
- C2- anterior cervix
- C3- anterior serosa at lower uterine segment
- C4- posterior serosa at lower uterine segment
- C5- posterior serosa near fundus
- C6- anterior serosa near fundus
- C7- posterior endomyometrium
- C8- anterior endomyometrium with 1 cm intramural leiomyoma

D. "Right pelvic peritoneum", received fresh and placed in formalin, is a 3.3 x 2.5 x 1.5 cm fragment of gray-yellow fibroadipose tissue. There is a discrete 1 x 0.9 x 0.4 cm tan firm nodule. Representative sections are submitted in blocks D1-2.

E. "Sigmoid nodule", received fresh and placed in formalin, is a 6 x 5 x 2 cm aggregate of tan-yellow fibroadipose tissue. There is a discrete 2 x 2 x 1.5 cm tan firm lesion. Representative sections are submitted in blocks E1-2.

F. "Right pelvic sidewall", received fresh and placed in formalin, is a 4 x 3 x 1 cm fragment of gray-yellow fibroadipose tissue. There are multiple ill-defined firm tan areas. Representative sections submitted in blocks F1-2.

G. "Rectum", received fresh and placed in formalin, is a 3.5 x 3 x 0.8 cm aggregate of brown-yellow fibroadipose tissue. There are multiple tan friable areas within the specimen. Representative section is submitted in block G1.

H. "Bladder peritoneum", received fresh and placed in formalin, is a 1 x 0.3 x 0.3 cm fragment of gray-yellow fibroadipose tissue. The specimen is submitted entirely in block H1.

I. "Terminal ileum", received fresh and placed in formalin, is a 3 x 2 x 1 cm fragment of brown-yellow fibroadipose tissue with a discrete 1.1 x 1 x 0.3 cm

[page 2 of 3]
fragment of firm papillary tissue. Representative sections are submitted in block I1.

J. "Infragastric omentum", received fresh and placed in formalin, is a 15 x 12 x 6 cm fragment of yellow lobulated omentum. There are multiple tan firm areas measuring up to 4 cm in greatest dimension. Representative sections are submitted in blocks J1-2.

K. "Cecal mass", received fresh and placed in formalin, is a 2 x 2 x 1 cm fragment of tan-yellow fibroadipose tissue with a poorly defined tan firm papillary area. Representative section is submitted in block K1.

L. "Right paraaortic node", received fresh and placed in formalin, is a 1.6 x 1 x 0.8 cm fragment of tan-yellow fibroadipose tissue. The specimen is bisected and one half is submitted in block L1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY

PATHOLOGIC STAGE pT3c pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A,B "RIGHT AND LEFT OVARIES":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 2

TUMOR SIZES: 7 X 5.5 X 3.5 CM AND 4.5 X 3.5 X 3 CM, RESPECTIVELY.

WEIGHT: 77 AND 36 GRAMS RESPECTIVELY

SEROSA: INVOLVED BOTH

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR

A. RIGHT FALLOPIAN TUBE.

B. LEFT FALLOPIAN TUBE.

C. UTERUS, 119 GRAMS

ENDOMETRIUM: ATROPHY

MYOMETRIUM: LEIOMYOMA, SMALL

TUMOR INVOLVES OUTER MYOMETRIUM AND LYMPHATIC VESSELS

CERVIX: TUMOR INVOLVES LYMPHATIC VESSELS

SEROSA: EXTENSIVELY INVOLVED WITH TUMOR.

D. RIGHT PELVIC PERITONEUM, EXTENSIVE TUMOR.

E. SIGMOID NODULE

F. RIGHT PELVIC SIDEWALL

G. RECTUM

H. BLADDER PERITONEUM

I. TERMINAL ILEUM

J. INFRAGASTRIC OMENTUM

K. CECAL MASS

L. RIGHT PARAAORTIC NODE: 1 OF 1 NODE INVOLVED

SPECIMENS FREE OF TUMOR:

NONE

I certify that I personally conducted the diagnostic evaluation of the above

[page 3 of 3]
specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1dc2d499-6a72-4d69-a5de-a59d326e2008 (TCGA-29-2431.CBD3DDD8-B431-4852-B4DB-B4BE535115D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).